Somatic mutation profile of tumor specimen TCGA-22-0944-01A (aliquot TCGA-22-0944-01A-01W-0782-08) from TCGA case TCGA-22-0944, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Age at diagnosis: 61.1 years (22,329 days).
Specimen TCGA-22-0944-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6761a337-8213-4be9-81c0-1a51d3875e09.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-22-0944-11A (Solid Tissue Normal), aliquot TCGA-22-0944-11A-01D-1521-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e508f397-3021-4ed4-a3d8-7ae09586d094

The open-access MAF lists 166 somatic variants for this specimen: 119 protein-altering or splice-affecting, 43 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 103, Silent 43, Nonsense Mutation 7, Intron 3, Frame Shift Del 3, Splice Site 3, Frame Shift Ins 1, 5'Flank 1, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.701A>G p.Y234C | Missense Mutation (SNP) | VAF 190/399 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs587780073, CM035576, COSV52661201, COSV52686167, COSV53142556; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS12 | c.4171T>A p.C1391S | Missense Mutation (SNP) | VAF 81/496 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV100711573, COSV61265839; called by muse, mutect2, varscan2
- AHCYL2 | c.859G>A p.D287N | Missense Mutation (SNP) | VAF 50/149 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV61488119; called by muse, mutect2, varscan2
- AKNAD1 | c.289A>T p.I97F | Missense Mutation (SNP) | VAF 65/137 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.44); catalogued as COSV62199562; called by muse, mutect2, varscan2
- AP1G1 | c.932A>G p.N311S | Missense Mutation (SNP) | VAF 86/253 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.294); catalogued as COSV55490812; called by muse, mutect2, varscan2
- ARMCX1 | c.211C>T p.Q71* | Nonsense Mutation (SNP) | VAF 6/90 reads (7%) | catalogued as COSV65704933; called by muse, mutect2
- ASXL1 | c.4099G>A p.V1367I | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs147456014; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BAZ1B | c.1327A>G p.M443V | Missense Mutation (SNP) | VAF 72/261 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.06); catalogued as rs1369392556, COSV59991914; called by muse, mutect2, varscan2
- BCL2L14 | c.940G>A p.G314R | Missense Mutation (SNP) | VAF 55/180 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866608585, COSV53789161; called by muse, mutect2, varscan2
- BMPR1A | c.587A>T p.D196V | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.049); catalogued as COSV64406566; called by muse, mutect2, varscan2
- CCDC136 | c.2245G>A p.G749S | Missense Mutation (SNP) | VAF 104/425 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.031); catalogued as COSV52800779, COSV99922678; called by muse, mutect2, varscan2
- CCDC181 | c.1318G>A p.E440K (on ENST00000367806 / NM_001300969.1; = p.E439K on NM_021179.2) | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV61393937; called by muse, mutect2, varscan2
- CCNY | c.794A>G p.N265S | Missense Mutation (SNP) | VAF 67/416 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs201763356, COSV55186162; called by muse, mutect2, varscan2
- CDH16 | c.1394C>A p.P465H | Missense Mutation (SNP) | VAF 80/116 reads (69%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.918); catalogued as COSV55337241; called by muse, mutect2, varscan2
- CDH20 | c.1916T>A p.I639N | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.374); catalogued as COSV53011796; called by muse, mutect2, varscan2
- CDH6 | c.1126G>T p.D376Y | Missense Mutation (SNP) | VAF 50/208 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54071928, COSV54076421; called by muse, mutect2, varscan2
- CECR2 | c.2494C>T p.R832* (on ENST00000342247 / NM_001290047.2; = p.R649* on NM_001290046.1) | Nonsense Mutation (SNP) | VAF 18/139 reads (13%) | catalogued as COSV52843326; called by muse, mutect2, varscan2
- CKMT2 | c.211G>A p.A71T | Missense Mutation (SNP) | VAF 94/143 reads (66%) | SIFT tolerated (0.17); PolyPhen benign (0.025); catalogued as rs548849398, COSV54172310; called by muse, mutect2
- CLN8 | c.796G>T p.A266S | Missense Mutation (SNP) | VAF 79/307 reads (26%) | SIFT tolerated (0.86); PolyPhen benign (0.007); catalogued as COSV58670826; called by muse, mutect2, varscan2
- CMTR2 | c.467A>C p.H156P | Missense Mutation (SNP) | VAF 149/285 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57603683; called by muse, mutect2, varscan2
- CNGA4 | c.1552C>A p.L518M | Missense Mutation (SNP) | VAF 93/240 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.269); catalogued as COSV101171858, COSV66006259; called by muse, mutect2, varscan2
- CNTNAP4 | c.2249C>A p.T750N | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs368916686, COSV56685755; called by muse, mutect2, varscan2
- CNTNAP5 | c.409A>C p.S137R | Missense Mutation (SNP) | VAF 38/230 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV70491150; called by muse, mutect2, varscan2
- CSF1 | c.973C>T p.P325S | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT tolerated (0.57); PolyPhen benign (0.019); catalogued as COSV60033880; called by muse, mutect2
- CSMD3 | c.5996G>T p.G1999V (on ENST00000297405 / NM_001363185.1; = p.G1895V on NM_052900.3) | Missense Mutation (SNP) | VAF 58/173 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV52211083, COSV52286393; called by muse, mutect2, varscan2
- DCAF4L2 | c.541del p.Q181Rfs*12 | Frame Shift Del (DEL) | VAF 71/222 reads (32%) | catalogued as COSV60479840; called by mutect2, pindel, varscan2
- DNM1L | c.695G>A p.G232E | Missense Mutation (SNP) | VAF 40/142 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56775100; called by muse, mutect2, varscan2
- DOCK5 | c.136A>G p.R46G | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as COSV52404065; called by mutect2, varscan2
- ELAC1 | c.703C>T p.P235S | Missense Mutation (SNP) | VAF 32/211 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.761); catalogued as COSV53996653; called by muse, mutect2, varscan2
- ENPEP | c.2212G>A p.D738N | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.027); catalogued as rs1170320206; called by muse, mutect2, varscan2
- ESYT3 | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56679808; called by muse, mutect2, varscan2
- FAM118A | c.152C>T p.S51L | Missense Mutation (SNP) | VAF 7/119 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1255998246, COSV53419478; called by muse, mutect2
- FAM217B | c.1000G>A p.D334N | Missense Mutation (SNP) | VAF 32/223 reads (14%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.929); catalogued as COSV62564568; called by muse, mutect2, varscan2
- FAT2 | c.11192C>T p.T3731I | Missense Mutation (SNP) | VAF 22/189 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as rs181781169; called by muse, mutect2, varscan2
- FAT3 | c.8792G>T p.G2931V | Missense Mutation (SNP) | VAF 85/231 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV53125955; called by muse, mutect2, varscan2
- FLI1 | c.908A>T p.E303V | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55645432; called by muse, mutect2, varscan2
- FLNC | c.6682C>T p.R2228W | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); catalogued as rs1196014760, COSV57957722, COSV57964509; called by mutect2, varscan2
- FLOT2 | c.1097A>T p.Q366L | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV101204736, COSV67529144; called by muse, mutect2, varscan2
- FRMD4A | c.461C>T p.S154F | Missense Mutation (SNP) | VAF 18/266 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.516); catalogued as rs1239847418; called by muse, mutect2
- FSIP2 | c.20260A>T p.M6754L | Missense Mutation (SNP) | VAF 77/248 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.034); catalogued as COSV58089234; called by muse, mutect2, varscan2
- GPRASP1 | c.2668G>T p.G890* | Nonsense Mutation (SNP) | VAF 139/220 reads (63%) | catalogued as COSV64355863; called by muse, mutect2, varscan2
- GRIA1 | c.1400G>A p.R467Q | Missense Mutation (SNP) | VAF 48/66 reads (73%) | SIFT tolerated (0.08); PolyPhen benign (0.313); catalogued as COSV53608082, COSV53627746; called by muse, mutect2, varscan2
- HIVEP3 | c.2155A>T p.K719* | Nonsense Mutation (SNP) | VAF 34/64 reads (53%) | catalogued as COSV56017149; called by muse, mutect2, varscan2
- IFNA5 | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 20/364 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1209353543; called by muse, mutect2
- KLHL1 | c.175A>C p.S59R | Missense Mutation (SNP) | VAF 60/99 reads (61%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.104); catalogued as COSV64774506; called by muse, mutect2, varscan2
- LRP1B | c.7999G>T p.D2667Y | Missense Mutation (SNP) | VAF 69/144 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV67234405; called by muse, mutect2, varscan2
- LRPPRC | c.2707A>T p.N903Y | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.24); catalogued as COSV53239643, COSV99581452; called by muse, mutect2, varscan2
- LRRC10 | c.381G>T p.W127C | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64060478; called by muse, mutect2, varscan2
- LRRC25 | c.343G>A p.D115N | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.967); catalogued as rs769281545, COSV59115315; called by muse, mutect2, varscan2
- MAGEB4 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.734); catalogued as COSV66775167, COSV66776489; called by muse, mutect2, varscan2
- MARK3 | c.1373G>T p.S458I | Missense Mutation (SNP) | VAF 38/57 reads (67%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV53511500; called by muse, mutect2, varscan2
- MMS19 | c.2126C>T p.S709L | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as rs746025168; called by muse, mutect2
- MORC3 | c.2794C>A p.Q932K | Missense Mutation (SNP) | VAF 54/137 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV68688500; called by muse, mutect2, varscan2
- MYO3A | c.722A>C p.K241T | Missense Mutation (SNP) | VAF 43/162 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56335150; called by muse, mutect2, varscan2
- NAV3 | c.1255G>T p.E419* | Nonsense Mutation (SNP) | VAF 120/287 reads (42%) | catalogued as COSV57087520; called by muse, mutect2, varscan2
- NOL4 | c.817C>T p.H273Y | Missense Mutation (SNP) | VAF 47/117 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.201); catalogued as rs1301908551, COSV52350401; called by muse, mutect2, varscan2
- NRXN1 | c.3392G>C p.G1131A | Missense Mutation (SNP) | VAF 41/267 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.204); catalogued as COSV58438772, COSV58462079; called by muse, mutect2, varscan2
- OR1Q1 | c.445C>A p.H149N | Missense Mutation (SNP) | VAF 48/368 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.278); catalogued as COSV52918275; called by muse, mutect2, varscan2
- OR2AG2 | c.495C>A p.H165Q | Missense Mutation (SNP) | VAF 72/184 reads (39%) | SIFT tolerated (0.43); PolyPhen benign (0.034); catalogued as COSV58455455, COSV58455517; called by muse, mutect2, varscan2
- OR52B2 | c.143T>A p.I48K | Missense Mutation (SNP) | VAF 220/609 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as COSV73209431; called by muse, mutect2, varscan2
- PCDHGA1 | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 10/258 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65297178; called by muse, mutect2
- PKNOX1 | c.683C>T p.T228I | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as COSV99372556; called by muse, mutect2, varscan2
- PM20D1 | c.436C>T p.R146C | Missense Mutation (SNP) | VAF 110/319 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.892); catalogued as rs1255981949, COSV65649095; called by muse, mutect2, varscan2
- PRCP | c.1208G>T p.R403M | Missense Mutation (SNP) | VAF 65/173 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV57289365; called by muse, mutect2, varscan2
- PRICKLE2 | c.313G>C p.V105L (on ENST00000295902; = p.V49L on NM_198859.4) | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55765734; called by muse, varscan2
- PRKCI | c.711G>A p.M237I | Missense Mutation (SNP) | VAF 20/415 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as rs1441299379; called by muse, mutect2
- PRKD1 | c.548A>G p.N183S | Missense Mutation (SNP) | VAF 156/239 reads (65%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as COSV59573091; called by muse, mutect2, varscan2
- PSMC5 | c.178C>T p.R60W | Missense Mutation (SNP) | VAF 45/224 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV56740051; called by muse, mutect2, varscan2
- PTPRJ | c.2444-2A>G p.X815_splice | Splice Site (SNP) | VAF 23/72 reads (32%) | catalogued as COSV69252824; called by muse, mutect2, varscan2
- PTPRM | c.1861T>C p.Y621H | Missense Mutation (SNP) | VAF 44/249 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV59864670; called by muse, mutect2, varscan2
- RP1 | c.4430A>T p.D1477V | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV55119112; called by muse, mutect2, varscan2
- RPTN | c.392A>T p.N131I | Missense Mutation (SNP) | VAF 183/1441 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.271); catalogued as COSV60167597; called by muse, mutect2, varscan2
- SATB1 | c.884C>G p.S295C | Missense Mutation (SNP) | VAF 62/115 reads (54%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV58667948, COSV58670095; called by muse, mutect2, varscan2
- SETBP1 | c.1234G>T p.D412Y | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.961); catalogued as COSV56325898; called by muse, mutect2, varscan2
- SH3GL2 | c.908C>A p.P303H | Missense Mutation (SNP) | VAF 90/139 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66051431; called by muse, mutect2, varscan2
- SIPA1L1 | c.2453A>T p.E818V | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV62170961; called by muse, mutect2, varscan2
- SLC35G5 | c.401G>C p.R134P | Missense Mutation (SNP) | VAF 104/434 reads (24%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.503); catalogued as COSV55313117; called by muse, varscan2
- SLC5A6 | c.209C>T p.P70L | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs752696770; called by muse, mutect2, varscan2
- SLC7A14 | c.2148C>A p.S716R | Missense Mutation (SNP) | VAF 33/198 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV51583946; called by muse, mutect2, varscan2
- SRGAP2 | c.1877C>T p.S626L (on ENST00000624873 / NM_001170637.4; = p.S627L on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 70/189 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55339009; called by muse, mutect2, varscan2
- TAS2R41 | c.758A>G p.D253G | Missense Mutation (SNP) | VAF 61/408 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.296); catalogued as COSV68765453; called by muse, mutect2, varscan2
- TECTA | c.5867G>A p.R1956Q | Missense Mutation (SNP) | VAF 93/317 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs780312128, COSV50724657; called by muse, mutect2, varscan2
- TENM3 | c.1159G>A p.E387K | Missense Mutation (SNP) | VAF 14/17 reads (82%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as COSV69311040; called by muse, mutect2, varscan2
- TLR5 | c.627T>G p.Y209* | Nonsense Mutation (SNP) | VAF 12/86 reads (14%) | catalogued as rs776525523, COSV60558898, COSV60559452; called by muse, mutect2, varscan2
- TNS3 | c.1921G>C p.V641L | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.138); catalogued as COSV60792915; called by muse, mutect2, varscan2
- TOE1 | c.52G>C p.G18R | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.187); catalogued as COSV59153427; called by muse, mutect2, varscan2
- TRAF6 | c.290C>T p.S97L | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.792); catalogued as COSV61922730; called by muse, mutect2
- TRPA1 | c.3243T>A p.D1081E | Missense Mutation (SNP) | VAF 112/308 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51562455, COSV51564412; called by muse, mutect2, varscan2
- TUBA3D | c.842C>T p.A281V | Missense Mutation (SNP) | VAF 94/159 reads (59%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.074); catalogued as COSV58312113; called by muse, mutect2, varscan2
- WBP11 | c.156G>C p.Q52H | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53763390, COSV99660929; called by muse, mutect2, varscan2
- WDR45 | c.851G>A p.G284E (on ENST00000376372 / NM_001029896.2; = p.G285E on NM_007075.3) | Missense Mutation (SNP) | VAF 19/30 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); catalogued as COSV59876278; called by muse, mutect2, varscan2
- XYLB | c.888G>T p.A296= | Splice Region (SNP) | VAF 48/102 reads (47%) | catalogued as COSV52913966; called by muse, mutect2, varscan2
- ZBTB49 | c.995G>A p.G332D | Missense Mutation (SNP) | VAF 47/93 reads (51%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV61925296; called by muse, mutect2, varscan2
- ZNF619 | c.523C>T p.L175F | Missense Mutation (SNP) | VAF 33/282 reads (12%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs367924884; called by muse, mutect2, varscan2
- ZNF665 | c.1498A>C p.T500P (on ENST00000600412; = p.T565P on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/145 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.408); catalogued as COSV67215730; called by muse, mutect2, varscan2
- ZNF721 | c.1598A>G p.Y533C (on ENST00000338977; = p.Y545C on NM_133474.4) | Missense Mutation (SNP) | VAF 78/163 reads (48%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as rs782005709, COSV59093674; called by muse, mutect2, varscan2
- ZNFX1 | c.1436G>A p.R479Q | Missense Mutation (SNP) | VAF 52/247 reads (21%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs770833497, COSV100870754; called by muse, mutect2, varscan2
- ABLIM1 | c.649C>T p.P217S | Missense Mutation (SNP) | VAF 16/220 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2
- ADH5 | c.382del p.S128Afs*33 | Frame Shift Del (DEL) | VAF 8/59 reads (14%) | called by mutect2, pindel, varscan2
- ATP9A | c.877-1G>A p.X293_splice | Splice Site (SNP) | VAF 82/397 reads (21%) | called by muse, mutect2, varscan2
- BCLAF1 | c.131C>T p.S44L | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.943); called by muse, mutect2
- BLMH | c.103G>A p.D35N | Missense Mutation (SNP) | VAF 34/130 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- CELF2 | c.763C>A p.Q255K (on ENST00000416382 / NM_001025077.3; = p.Q262K on NM_006561.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/438 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.165); called by muse, mutect2
- CELSR1 | c.1135del p.D379Tfs*31 | Frame Shift Del (DEL) | VAF 418/425 reads (98%) | called by mutect2*, varscan2
- FBN1 | c.1942G>A p.D648N | Missense Mutation (SNP) | VAF 121/468 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); called by muse, varscan2
- FSD1 | c.346-1G>A p.X116_splice | Splice Site (SNP) | VAF 247/848 reads (29%) | called by muse, mutect2, varscan2
- ITGA10 | c.1438dup p.E480Gfs*10 | Frame Shift Ins (INS) | VAF 11/54 reads (20%) | called by mutect2, pindel, varscan2
- KATNIP | c.4693G>A p.E1565K | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- MFN1 | c.368C>T p.A123V | Missense Mutation (SNP) | VAF 27/662 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2
- RASGRF1 | c.3113C>A p.S1038* | Nonsense Mutation (SNP) | VAF 35/261 reads (13%) | called by muse, mutect2, varscan2
- SETD2 | c.4607G>A p.G1536E | Missense Mutation (SNP) | VAF 34/164 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- SETD2 | c.4606G>A p.G1536R | Missense Mutation (SNP) | VAF 32/161 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- SPATA31A3 | c.762G>T p.L254F | Missense Mutation (SNP) | VAF 38/144 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.274); called by mutect2, varscan2
- TARS2 | c.680C>A p.T227K | Missense Mutation (SNP) | VAF 9/158 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2
- TMED6 | c.289G>T p.D97Y | Missense Mutation (SNP) | VAF 22/688 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.853); called by muse, mutect2
- UNC45A | c.1699G>A p.D567N | Missense Mutation (SNP) | VAF 24/182 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- UNC45A | c.1890_1898del p.S630_V632del | In Frame Del (DEL) | VAF 26/74 reads (35%) | called by mutect2, pindel, varscan2
- ZNF17 | c.592G>T p.D198Y | Missense Mutation (SNP) | VAF 12/232 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.227); called by muse, mutect2
- ZNF17 | c.593A>T p.D198V | Missense Mutation (SNP) | VAF 12/229 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.03); called by muse, mutect2
- ABCB9 | c.1710C>T p.I570= (on ENST00000280560 / NM_019625.4; = p.I527= on NM_019624.3) | Silent (SNP) | VAF 5/26 reads (19%) | called by muse, mutect2, varscan2
- ACSBG2 | c.1503C>T p.D501= | Silent (SNP) | VAF 39/247 reads (16%) | catalogued as rs371212782; called by muse, mutect2, varscan2
- ARHGAP31 | c.1371G>C p.S457= | Silent (SNP) | VAF 34/99 reads (34%) | catalogued as COSV51789804, COSV51794480; called by muse, mutect2, varscan2
- ATP1A1 | c.1992A>T p.V664= | Silent (SNP) | VAF 114/219 reads (52%) | catalogued as COSV55191951; called by muse, mutect2, varscan2
- B2M | c.108G>A p.E36= | Silent (SNP) | VAF 29/319 reads (9%) | catalogued as COSV62563143, COSV62564821; called by muse, mutect2
- CCDC190 | c.738C>T p.F246= | Silent (SNP) | VAF 50/162 reads (31%) | catalogued as COSV63363624; called by muse, varscan2
- CHAF1A | c.1728G>A p.K576= | Silent (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2, varscan2
- CIAO1 | c.882G>T p.L294= | Silent (SNP) | VAF 12/181 reads (7%) | called by muse, mutect2
- CKMT2 | c.213C>A p.A71= | Silent (SNP) | VAF 90/144 reads (63%) | catalogued as COSV54173763; called by muse, mutect2
- CNGA2 | c.786G>T p.R262= | Silent (SNP) | VAF 228/341 reads (67%) | catalogued as COSV61705012; called by muse, mutect2, varscan2
- COL15A1 | c.1551C>G p.P517= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as COSV66646216; called by muse, mutect2, varscan2
- CSMD3 | c.9162G>T p.G3054= (on ENST00000297405 / NM_001363185.1; = p.G2885= on NM_052900.3) | Silent (SNP) | VAF 41/138 reads (30%) | catalogued as COSV52211050; called by muse, mutect2, varscan2
- DTX1 | c.1059C>G p.A353= | Silent (SNP) | VAF 22/47 reads (47%) | catalogued as COSV57498468, COSV57500819; called by muse, mutect2, varscan2
- DYSF | c.4725C>G p.P1575= | Silent (SNP) | VAF 40/231 reads (17%) | catalogued as COSV50451631; called by muse, mutect2, varscan2
- FANCA | c.2127G>T p.P709= | Silent (SNP) | VAF 38/171 reads (22%) | catalogued as COSV66881996, COSV66882448; called by muse, mutect2, varscan2
- FBN1 | c.1941G>A p.L647= | Silent (SNP) | VAF 116/462 reads (25%) | called by muse, varscan2
- FLNB | c.1710C>T p.F570= | Silent (SNP) | VAF 20/68 reads (29%) | catalogued as rs551771569, COSV55874452, COSV99912105; called by mutect2, varscan2
- GIMAP8 | c.1761T>A p.L587= | Silent (SNP) | VAF 55/160 reads (34%) | catalogued as COSV56232181; called by muse, mutect2, varscan2
- GLI3 | c.2769C>T p.P923= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs761730228, COSV67889878; called by mutect2, varscan2
- IGHV1-46 | c.93G>A p.K31= | Silent (SNP) | VAF 11/274 reads (4%) | catalogued as rs1555524859; called by muse, mutect2
- IGLJ7 | c.46G>T p.*16= | Silent (SNP) | VAF 30/78 reads (38%) | called by muse, mutect2
- L1CAM | c.603C>T p.S201= | Silent (SNP) | VAF 31/49 reads (63%) | catalogued as rs782223025, COSV62828583; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRFN5 | c.567G>A p.G189= | Silent (SNP) | VAF 27/56 reads (48%) | catalogued as COSV53261249; called by muse, mutect2, varscan2
- LRRN3 | c.726T>G p.S242= | Silent (SNP) | VAF 34/120 reads (28%) | catalogued as COSV57820892; called by muse, mutect2, varscan2
- LRRTM4 | c.729C>T p.S243= | Silent (SNP) | VAF 8/71 reads (11%) | catalogued as COSV69139993; called by mutect2, varscan2
- NECTIN2 | c.663C>T p.S221= | Silent (SNP) | VAF 12/276 reads (4%) | called by muse, mutect2
- NRAP | c.1086G>A p.Q362= | Silent (SNP) | VAF 11/169 reads (7%) | catalogued as rs776081863; called by muse, mutect2
- OR1L4 | c.891T>C p.D297= | Silent (SNP) | VAF 60/158 reads (38%) | catalogued as COSV52340279; called by muse, mutect2, varscan2
- OVCH1 | c.2094T>C p.C698= | Silent (SNP) | VAF 11/66 reads (17%) | catalogued as COSV58964479; called by muse, mutect2, varscan2
- PARD3B | c.3609A>G p.A1203= (on ENST00000406610 / NM_001302769.2; = p.A1134= on NM_057177.7) | Silent (SNP) | VAF 117/180 reads (65%) | catalogued as rs1231266269, COSV62515389; called by muse, mutect2, varscan2
- PDE1A | c.307C>A p.R103= | Silent (SNP) | VAF 120/560 reads (21%) | catalogued as rs1252203134, COSV59515352, COSV59526039; called by muse, mutect2, varscan2
- PLVAP | c.384C>T p.N128= | Silent (SNP) | VAF 21/219 reads (10%) | catalogued as rs1568375687, COSV53085807; called by muse, mutect2
- PTPRF | c.375C>G p.L125= | Silent (SNP) | VAF 40/68 reads (59%) | catalogued as rs768382559, COSV63445965; called by muse, mutect2, varscan2
- RALGAPA1 | c.3681C>T p.L1227= | Silent (SNP) | VAF 6/67 reads (9%) | called by muse, mutect2
- RD3 | c.51C>T p.S17= | Silent (SNP) | VAF 34/102 reads (33%) | catalogued as rs1234982419, COSV65362436; called by muse, mutect2, varscan2
- RIMKLA | c.297C>T p.V99= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as rs772577198; called by muse, mutect2, varscan2
- SLC35G5 | c.402C>T p.R134= | Silent (SNP) | VAF 104/432 reads (24%) | catalogued as COSV55313122; called by muse, varscan2
- SLC5A11 | c.1197C>T p.I399= | Silent (SNP) | VAF 131/395 reads (33%) | called by muse, mutect2, varscan2
- SLC6A2 | c.696G>T p.L232= | Silent (SNP) | VAF 36/85 reads (42%) | catalogued as rs768200271, COSV54917802; called by muse, mutect2, varscan2
- SMYD2 | c.144G>T p.R48= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as COSV65291091; called by muse, mutect2, varscan2
- ST8SIA5 | c.153G>T p.G51= | Silent (SNP) | VAF 108/343 reads (31%) | catalogued as rs745497654, COSV59332747; called by muse, mutect2, varscan2
- TMEM106B | c.420T>G p.R140= | Silent (SNP) | VAF 46/306 reads (15%) | catalogued as rs140753733; called by muse, mutect2
- UTP20 | c.5542C>T p.L1848= | Silent (SNP) | VAF 14/66 reads (21%) | catalogued as COSV55378997; called by muse, mutect2, varscan2
- ADARB2 | c.101-147719G>T | Intron (SNP) | VAF 40/780 reads (5%) | catalogued as COSV101184488; called by muse, mutect2
- ASPH | c.323-11701G>T | Intron (SNP) | VAF 39/121 reads (32%) | catalogued as COSV100727552; called by muse, mutect2
- NOP58 | c.122+1298_122+1300del | Intron (DEL) | VAF 12/48 reads (25%) | called by pindel, varscan2
- SUCO | chr1:172532705 C>T | 5'Flank (SNP) | VAF 9/51 reads (18%) | catalogued as rs1204536930, COSV99742107; called by muse, mutect2, varscan2
